Somatic mutation profile of tumor specimen C3N-02144-02 (aliquot CPT0213400009) from CPTAC case C3N-02144, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 71.9 years (26,253 days).
Specimen C3N-02144-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 291d2b8c-13fe-4cdf-b97b-34080f1b44e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02144-71 (Blood Derived Normal), aliquot CPT0213510002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb7e62dd-4796-41ff-90fa-87855bd5089a

The open-access MAF lists 122 somatic variants for this specimen: 80 protein-altering or splice-affecting, 26 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 26, Intron 11, Splice Site 4, Nonsense Mutation 3, 5'UTR 2, RNA 2, Frame Shift Del 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH7 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 181/880 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913625, CM087715, CM920490, COSV62516285; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGRN | c.5738C>G p.T1913R | Missense Mutation (SNP) | VAF 52/644 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.756); catalogued as rs201604787; called by muse, mutect2
- ATP1B4 | c.773G>A p.R258H (on ENST00000218008 / NM_001142447.3; = p.R254H on NM_012069.5) | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs143954745, COSV54312118, COSV54315710; called by muse, mutect2, varscan2
- C6orf118 | c.359C>A p.P120H | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100023992; called by muse, mutect2, varscan2
- CACNA1B | c.1038C>A p.F346L | Missense Mutation (SNP) | VAF 38/398 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV53127082, COSV53150083; called by muse, mutect2
- CAVIN3 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58269451; called by muse, mutect2
- CD209 | c.310C>A p.L104M | Missense Mutation (SNP) | VAF 66/884 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1292941053; called by muse, mutect2
- CTNNA2 | c.2258C>T p.S753F | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58153166; called by muse, mutect2
- DACT2 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs1202698562, COSV64693958; called by muse, mutect2, varscan2
- DNAH3 | c.9229C>T p.R3077C | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372316224; called by muse, mutect2, varscan2
- EPM2A | c.152C>A p.A51D | Missense Mutation (SNP) | VAF 47/306 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.229); catalogued as rs1057524725; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FSTL5 | c.1599A>T p.K533N | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV60213555; called by muse, varscan2
- KCNG2 | c.479G>T p.R160L | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as rs776506547; called by mutect2, varscan2
- KIR2DL4 | c.521C>T p.T174M (on ENST00000396284; = p.T135M on NM_001080770.2) | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.059); catalogued as rs376428959; called by muse, mutect2
- KRT8 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 49/266 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.258); catalogued as rs147715492, COSV53177970, COSV99509910; called by muse, mutect2, varscan2
- KTI12 | c.220G>T p.D74Y | Missense Mutation (SNP) | VAF 35/315 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100860204, COSV65405981; called by muse, mutect2, varscan2
- LAMP5 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 20/332 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1327688705, COSV55717453; called by muse, mutect2
- OR4Q2 | c.539A>G p.D180G | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1412488703; called by muse, mutect2
- POLM | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs750258630, COSV54243070; called by muse, mutect2, varscan2
- POM121L12 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 40/510 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.736); catalogued as rs565591382, COSV101374974; called by muse, mutect2
- RNF213 | c.2183C>T p.S728L | Missense Mutation (SNP) | VAF 32/368 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.237); catalogued as COSV60628569; called by muse, mutect2
- SMC4 | c.520G>C p.D174H | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV58449447; called by muse, mutect2
- SORT1 | c.35C>A p.S12* | Nonsense Mutation (SNP) | VAF 49/254 reads (19%) | catalogued as rs1368145155; called by muse, mutect2, varscan2
- UNKL | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 36/499 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749632739; called by muse, mutect2
- ZBTB4 | c.1058C>G p.T353R | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1327015754; called by muse, varscan2
- ZNF845 | c.2060G>A p.G687E | Missense Mutation (SNP) | VAF 22/379 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs757923688; called by muse, mutect2
- AADACL2 | c.945C>A p.S315R | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ACSL5 | c.631C>G p.L211V (on ENST00000354273; = p.L267V on NM_016234.3) | Missense Mutation (SNP) | VAF 21/259 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.015); called by muse, mutect2
- ANKRD34A | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ASTN1 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 14/213 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- BDP1 | c.6068A>T p.H2023L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- BMP5 | c.418C>A p.P140T | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- C1orf43 | c.705C>G p.H235Q (on ENST00000368521 / NM_001297718.2; = p.H201Q on NM_015449.4) | Missense Mutation (SNP) | VAF 59/277 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- CCT2 | c.33C>G p.I11M | Missense Mutation (SNP) | VAF 24/606 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- CDC40 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDR2L | c.179dup p.Q61Afs*25 | Frame Shift Ins (INS) | VAF 28/135 reads (21%) | called by mutect2, pindel, varscan2
- CES4A | c.1264C>A p.Q422K | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CPO | c.373-1G>T p.X125_splice | Splice Site (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- DENND1B | c.689A>G p.H230R | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.364); called by muse, mutect2
- FOXP2 | c.167A>G p.Q56R | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- GASK1A | c.778T>C p.W260R | Missense Mutation (SNP) | VAF 39/378 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GPR162 | c.1455T>A p.S485R (on ENST00000311268 / NM_019858.2; = p.S201R on NM_014449.2) | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- GUCA1A | c.164A>G p.Y55C | Missense Mutation (SNP) | VAF 61/375 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HDAC4 | c.791G>C p.R264P | Missense Mutation (SNP) | VAF 43/413 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- KCP | c.1241A>T p.Q414L (on ENST00000620378; = p.Q471L on NM_001366122.1) | Missense Mutation (SNP) | VAF 60/214 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- KLHL36 | c.1147A>G p.M383V | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2
- KRT78 | c.1331C>A p.S444Y | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LAMB3 | c.940C>G p.Q314E | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- MET | c.3022_3028+3del p.X1008_splice | Splice Site (DEL) | VAF 45/182 reads (25%) | called by mutect2, pindel, varscan2
- MTCH1 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 85/517 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- MUC12 | c.2038C>A p.P680T (on ENST00000379442; = p.P537T on NM_001164462.1) | Missense Mutation (SNP) | VAF 45/919 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.65); called by muse, mutect2
- MUC16 | c.39980T>A p.L13327H | Missense Mutation (SNP) | VAF 58/572 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- MYOD1 | c.418C>A p.P140T | Missense Mutation (SNP) | VAF 29/329 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NAP1L1 | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2, varscan2
- NFATC4 | c.1130A>G p.Y377C | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- NPAS3 | c.671G>A p.G224D (on ENST00000356141 / NM_001164749.2; = p.G192D on NM_022123.3) | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- PASK | c.3952C>T p.P1318S | Missense Mutation (SNP) | VAF 80/411 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- PCDHA6 | c.1451C>T p.A484V | Missense Mutation (SNP) | VAF 157/959 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- PIAS3 | c.1684T>C p.Y562H | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.795); called by muse, mutect2
- PNPLA6 | c.2056G>C p.E686Q (on ENST00000414982 / NM_001166111.2; = p.E638Q on NM_006702.5) | Missense Mutation (SNP) | VAF 125/601 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- POU3F3 | c.712C>A p.P238T | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.981); called by muse, varscan2
- PTPRD | c.2567A>G p.Y856C | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRZ1 | c.3746C>A p.T1249N | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.205); called by muse, mutect2
- RC3H2 | c.2017C>T p.Q673* | Nonsense Mutation (SNP) | VAF 18/118 reads (15%) | called by muse, mutect2, varscan2
- SAGE1 | c.1442-1G>T p.X481_splice | Splice Site (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- SFTA2 | c.77T>C p.L26S | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- SH3PXD2B | c.2719C>T p.L907F | Missense Mutation (SNP) | VAF 48/467 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- STK11IP | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 46/512 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.172); called by muse, mutect2
- SYNPR | c.114C>A p.N38K | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.045); called by muse, mutect2
- TAS2R50 | c.786G>A p.M262I | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- TBCE | c.1327G>C p.E443Q (on ENST00000366601; = p.E506Q on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/418 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- TEX14 | c.3217C>T p.P1073S (on ENST00000240361 / NM_001201457.2; = p.P1067S on NM_198393.4) | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TXNDC5 | c.702del p.E235Nfs*52 | Frame Shift Del (DEL) | VAF 24/254 reads (9%) | called by mutect2, pindel
- UBE4A | c.2329G>A p.E777K (on ENST00000252108 / NM_001204077.2; = p.E784K on NM_004788.4) | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- UCP1 | c.228C>A p.S76R | Missense Mutation (SNP) | VAF 57/741 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.109); called by muse, mutect2
- USH2A | c.4960A>C p.S1654R | Missense Mutation (SNP) | VAF 16/231 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2
- VASN | c.821T>G p.L274R | Missense Mutation (SNP) | VAF 28/348 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ZDHHC11 | c.948G>C p.K316N | Missense Mutation (SNP) | VAF 30/257 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- ZNF449 | c.1427C>A p.P476Q | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ZNF599 | c.242-1G>T p.X81_splice | Splice Site (SNP) | VAF 11/70 reads (16%) | called by muse, varscan2
- ALMS1 | c.1710A>G p.V570= | Silent (SNP) | VAF 14/211 reads (7%) | called by muse, mutect2
- APLP1 | c.1839C>T p.I613= (on ENST00000221891 / NM_001024807.3; = p.I612= on NM_005166.4) | Silent (SNP) | VAF 19/137 reads (14%) | catalogued as rs530050323, COSV55702300, COSV55702436; called by muse, mutect2, varscan2
- ATP1A3 | c.2781G>A p.V927= (on ENST00000545399 / NM_001256214.2; = p.V914= on NM_152296.5) | Silent (SNP) | VAF 72/737 reads (10%) | catalogued as COSV57487521; called by muse, mutect2, varscan2
- CARMIL1 | c.3765G>T p.P1255= | Silent (SNP) | VAF 40/406 reads (10%) | catalogued as COSV61514991, COSV61517077; called by muse, mutect2
- CELSR1 | c.3780G>C p.V1260= | Silent (SNP) | VAF 40/547 reads (7%) | called by muse, mutect2
- COL27A1 | c.5184A>G p.G1728= | Silent (SNP) | VAF 21/123 reads (17%) | called by muse, mutect2, varscan2
- CSF1R | c.2887T>C p.L963= | Silent (SNP) | VAF 28/342 reads (8%) | called by muse, mutect2
- DNAH1 | c.2958G>A p.L986= | Silent (SNP) | VAF 11/263 reads (4%) | called by muse, mutect2
- DPY19L2 | c.1428C>T p.T476= | Silent (SNP) | VAF 48/105 reads (46%) | called by muse, mutect2, varscan2
- ERICH6 | c.1542C>T p.A514= | Silent (SNP) | VAF 14/119 reads (12%) | catalogued as rs776550362; called by muse, mutect2, varscan2
- ESYT2 | c.747C>T p.I249= (on ENST00000613624; = p.I173= on NM_020728.3) | Silent (SNP) | VAF 6/108 reads (6%) | catalogued as COSV99277288; called by muse, mutect2
- FBN1 | c.4500G>T p.G1500= | Silent (SNP) | VAF 106/412 reads (26%) | called by muse, mutect2, varscan2
- GABRA5 | c.612C>A p.V204= | Silent (SNP) | VAF 51/347 reads (15%) | called by muse, mutect2, varscan2
- KIAA1210 | c.4314G>A p.R1438= | Silent (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- MINDY4 | c.1227C>T p.L409= | Silent (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- MLXIPL | c.435C>T p.F145= | Silent (SNP) | VAF 36/456 reads (8%) | catalogued as rs1554598751, COSV57667523; called by muse, mutect2
- PLXNA4 | c.303C>T p.V101= | Silent (SNP) | VAF 27/200 reads (14%) | catalogued as rs753681070; called by muse, mutect2, varscan2
- PRKAG3 | c.900C>T p.L300= | Silent (SNP) | VAF 84/410 reads (20%) | called by muse, mutect2, varscan2
- PTGER3 | c.168C>T p.I56= | Silent (SNP) | VAF 44/321 reads (14%) | called by muse, mutect2, varscan2
- RBM39 | c.274A>C p.R92= | Silent (SNP) | VAF 30/270 reads (11%) | called by muse, mutect2, varscan2
- RPTN | c.75T>C p.C25= | Silent (SNP) | VAF 36/265 reads (14%) | called by muse, mutect2, varscan2
- SAP30 | c.186C>T p.G62= | Silent (SNP) | VAF 39/227 reads (17%) | catalogued as rs1436579754; called by muse, mutect2, varscan2
- SLC6A3 | c.360C>T p.L120= | Silent (SNP) | VAF 47/590 reads (8%) | catalogued as rs148447720; ClinVar: likely benign; called by muse, mutect2
- SLCO4A1 | c.1887G>A p.P629= | Silent (SNP) | VAF 22/186 reads (12%) | catalogued as rs375451890; called by muse, mutect2, varscan2
- TUBB4B | c.765G>A p.V255= | Silent (SNP) | VAF 48/568 reads (8%) | catalogued as rs773338441; called by muse, mutect2
- ZNF679 | c.936T>A p.T312= | Silent (SNP) | VAF 18/269 reads (7%) | called by muse, mutect2
- BABAM2 | c.1088+11592A>G | Intron (SNP) | VAF 15/162 reads (9%) | called by muse, mutect2
- DGKZ | c.2907-92G>A | Intron (SNP) | VAF 49/259 reads (19%) | catalogued as rs1044063250; called by muse, mutect2, varscan2
- DNAJC13 | c.6626-1000T>C | Intron (SNP) | VAF 30/413 reads (7%) | catalogued as rs908898887; called by muse, mutect2
- EIF4A1 | c.-3A>T | 5'UTR (SNP) | VAF 24/324 reads (7%) | catalogued as rs778405177, COSV53443904; called by muse, mutect2
- FBXO3 | c.1239+72A>G | Intron (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2, varscan2
- GOLGA8R | c.348+58T>A | Intron (SNP) | VAF 54/302 reads (18%) | called by mutect2, varscan2
- HBS1L | c.430+2518C>G | Intron (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- KHSRP | c.2127+14G>T | Intron (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- MS4A2 | c.538-18T>A | Intron (SNP) | VAF 52/298 reads (17%) | called by muse, mutect2, varscan2
- OFCC1 | n.1398G>C | RNA (SNP) | VAF 9/139 reads (6%) | called by muse, mutect2
- OR4C4P | n.174G>C | RNA (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- POPDC3 | c.-251-4530A>T | Intron (SNP) | VAF 10/78 reads (13%) | called by muse, mutect2
- RANBP1 | c.310+156C>G | Intron (SNP) | VAF 32/388 reads (8%) | called by muse, mutect2
- SERPING1 | c.890-49A>G | Intron (SNP) | VAF 18/223 reads (8%) | called by muse, mutect2
- SLC38A4 | c.*188T>A | 3'UTR (SNP) | VAF 12/99 reads (12%) | called by muse, mutect2, varscan2
- ZNF879 | c.-3G>T | 5'UTR (SNP) | VAF 31/279 reads (11%) | called by muse, mutect2, varscan2
